FM case AD14283 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/860a577f-6eac-43be-aaf5-67ef4e6b3882

Female, 69.1 years: Large cell neuroendocrine carcinoma (ICD-O-3 8013/3) of the lung; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
